Somatic mutation profile of tumor specimen TCGA-FF-8043-01A (aliquot TCGA-FF-8043-01A-11D-2210-10) from TCGA case TCGA-FF-8043, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Colon, NOS; Age at diagnosis: 70.1 years (25,612 days).
Specimen TCGA-FF-8043-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37e31c00-3f54-4ad2-ad2b-2294e269df05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FF-8043-10A (Blood Derived Normal), aliquot TCGA-FF-8043-10A-01D-2210-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33e44776-e23e-43aa-a0a9-2cc6c59d3116

The open-access MAF lists 108 somatic variants for this specimen: 74 protein-altering or splice-affecting, 27 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 27, Nonsense Mutation 4, 5'Flank 3, Frame Shift Del 2, Splice Region 2, 5'UTR 2, 3'UTR 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNQ3 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1381851622, COSV66464105; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 67/75 reads (89%) | catalogued as rs587781845, COSV52671445, COSV52701260, COSV52703282; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.1824+1G>A p.X608_splice | Splice Site (SNP) | VAF 96/148 reads (65%) | catalogued as COSV100579370; called by muse, mutect2, varscan2
- ARAP3 | c.4207T>C p.Y1403H | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated, low confidence (0.48); PolyPhen probably damaging (0.969); catalogued as COSV53351375; called by muse, mutect2, varscan2
- B2M | c.343T>G p.W115G | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62565358; called by muse, mutect2, varscan2
- BMP2 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as rs1418608910; called by muse, mutect2, varscan2
- BRSK2 | c.1166C>T p.T389M | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368418167; called by muse, mutect2, varscan2
- CLCN2 | c.1831A>C p.M611L | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV99658656; called by muse, mutect2, varscan2
- DGKB | c.2210G>T p.G737V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51778972; called by muse, mutect2, varscan2
- DGKB | c.2069G>T p.G690V | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV51789103; called by muse, mutect2, varscan2
- DST | c.17975T>C p.L5992S (on ENST00000361203 / NM_001374722.1; = p.L3689S on NM_015548.5) | Missense Mutation (SNP) | VAF 88/224 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.069); catalogued as rs1431402571; called by muse, mutect2, varscan2
- ELFN1 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs563858883; called by muse, mutect2, varscan2
- EYS | c.2719G>T p.D907Y | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs1174460634; called by muse, mutect2, varscan2
- GP2 | c.1478G>A p.R493Q (on ENST00000381362 / NM_001007240.3; = p.R490Q on NM_001502.4) | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as rs770032956, COSV100221692, COSV56893889; called by muse, mutect2, varscan2
- IGKJ4 | c.34A>C p.K12Q | Missense Mutation (SNP) | VAF 46/112 reads (41%) | PolyPhen benign (0.018); catalogued as rs371864920; called by muse, varscan2
- KCNT1 | c.2699C>T p.T900M (on ENST00000488444; = p.T919M on NM_020822.3) | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1213818774, COSV53710912; called by muse, mutect2, varscan2
- KMT2D | c.2419dup p.S807Ffs*5 | Frame Shift Ins (INS) | VAF 134/203 reads (66%) | catalogued as COSV56423276; called by mutect2, varscan2
- LITAF | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 38/278 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1187778697; called by muse, mutect2, varscan2
- LRRC4B | c.2015C>T p.A672V | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.173); catalogued as rs770871502, COSV65349620; called by muse, mutect2, varscan2
- MMP2 | c.442T>A p.F148I | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV99527713; called by muse, mutect2
- MROH8 | c.254C>T p.T85I | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.114); catalogued as COSV99027954; called by muse, mutect2
- MYOG | c.566C>T p.T189M | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs534586936, COSV54095370; called by muse, mutect2, varscan2
- NCAM2 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as rs576610818, COSV53075049, COSV53081210; called by muse, mutect2, varscan2
- NRG2 | c.990C>T p.S330= | Splice Region (SNP) | VAF 25/80 reads (31%) | catalogued as rs765915567, COSV56834910, COSV56839255; called by muse, mutect2, varscan2
- ORC1 | c.2536C>T p.R846W | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs767264406; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POMT2 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as rs571330846, COSV55074075; called by muse, mutect2, varscan2
- PSME4 | c.2740C>T p.R914* | Nonsense Mutation (SNP) | VAF 39/51 reads (76%) | catalogued as rs1162295962; called by muse, mutect2, varscan2
- PTGER3 | c.1110T>G p.N370K (on ENST00000370932; = p.F371V on NM_198716.2) | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV63385792; called by muse, mutect2, varscan2
- RABL3 | c.623A>G p.Y208C | Missense Mutation (SNP) | VAF 94/216 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as rs1226479288; called by muse, mutect2, varscan2
- RAPGEF3 | c.607G>A p.E203K (on ENST00000389212; = p.E161K on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV50198807; called by muse, mutect2, varscan2
- RP1 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 81/186 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.11); catalogued as rs756961463, COSV55113657; called by muse, mutect2, varscan2
- SMC5 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 108/252 reads (43%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.602); catalogued as rs115131883; called by muse, mutect2
- SSR1 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.677); catalogued as rs1231363949; called by muse, mutect2, varscan2
- SULT1A1 | c.453G>C p.E151D | Missense Mutation (SNP) | VAF 230/359 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1042014; called by muse, mutect2, varscan2
- TUBB4A | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as rs1053267, COSV99900008; called by muse, mutect2, varscan2
- VARS2 | c.3095C>T p.S1032F | Missense Mutation (SNP) | VAF 117/283 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs747034589; called by muse, mutect2, varscan2
- WNT5A | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 71/140 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV52837570; called by muse, mutect2, varscan2
- ZNF20 | c.1472A>G p.N491S | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs557758485; called by muse, mutect2, varscan2
- ADAMTS7 | c.1861C>G p.P621A | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- AHNAK2 | c.3780C>A p.D1260E | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- AMN | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.95); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- AMOTL1 | c.1660T>G p.L554V | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ATF7IP | c.1301A>G p.E434G | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- BTG1 | c.185G>A p.C62Y | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BTG1 | c.132_138del p.Q45Cfs*33 | Frame Shift Del (DEL) | VAF 43/109 reads (39%) | called by mutect2, pindel, varscan2
- CCP110 | c.2582C>T p.A861V | Missense Mutation (SNP) | VAF 148/377 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- COL11A1 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- CTSH | c.642C>G p.C214W | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK1 | c.4291G>T p.V1431L | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- DPH6 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 115/149 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- EBF3 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, varscan2
- FAM47C | c.1831C>T p.P611S | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- HOXC13 | c.617A>G p.D206G | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- IGHM | c.365G>A p.G122D | Missense Mutation (SNP) | VAF 44/56 reads (79%) | SIFT deleterious (0.03); called by muse, mutect2, varscan2
- JSRP1 | c.254C>A p.A85D | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- KIF17 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KRTAP2-4 | c.362C>T p.T121I | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- MAGI2 | c.1607T>C p.V536A | Missense Mutation (SNP) | VAF 120/262 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MLXIP | c.230T>C p.I77T | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MPO | c.509A>C p.Q170P | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NR2C1 | c.1131G>A p.R377= | Splice Region (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2, varscan2
- P2RY8 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 42/49 reads (86%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- PAK5 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 116/372 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- PCBP3 | c.718C>G p.Q240E | Missense Mutation (SNP) | VAF 82/140 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SARDH | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 39/79 reads (49%) | called by muse, mutect2, varscan2
- STYXL2 | c.1497del p.S499Rfs*78 | Frame Shift Del (DEL) | VAF 70/178 reads (39%) | called by mutect2, pindel, varscan2
- SUPT6H | c.1876A>G p.K626E | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- TFG | c.996A>T p.Q332H | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TRIM77 | c.787C>G p.P263A | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- USH2A | c.15096C>A p.S5032R | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- WFDC9 | c.26T>C p.V9A | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZBTB22 | c.1417G>C p.V473L | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF224 | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2, varscan2
- CDH5 | c.735G>A p.L245= | Silent (SNP) | VAF 49/80 reads (61%) | catalogued as COSV58520156; called by muse, varscan2
- CSMD1 | c.4029C>T p.D1343= (on ENST00000520002; = p.D1342= on NM_033225.6) | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs759150050; called by muse, mutect2, varscan2
- DTX1 | c.138C>T p.H46= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as rs775900132; called by muse, varscan2
- ENPP7 | c.666C>T p.T222= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs782473022, COSV100093552; called by muse, mutect2, varscan2
- EXOG | c.96G>A p.G32= | Silent (SNP) | VAF 42/80 reads (53%) | called by muse, mutect2, varscan2
- FAF1 | c.189A>T p.G63= | Silent (SNP) | VAF 49/130 reads (38%) | called by muse, mutect2, varscan2
- FAM43A | c.795G>A p.E265= | Silent (SNP) | VAF 82/165 reads (50%) | catalogued as rs1404315180; called by muse, mutect2, varscan2
- FHAD1 | c.429G>A p.P143= | Silent (SNP) | VAF 52/127 reads (41%) | catalogued as rs532174986; called by muse, mutect2, varscan2
- IGHV3-7 | c.292C>T p.L98= | Silent (SNP) | VAF 82/468 reads (18%) | catalogued as rs782818014; called by muse, mutect2
- IGLV3-1 | c.60C>T p.S20= | Silent (SNP) | VAF 14/18 reads (78%) | catalogued as rs577917177; called by muse, varscan2
- IPO5 | c.2466A>G p.E822= | Silent (SNP) | VAF 5/73 reads (7%) | catalogued as COSV99847205; called by muse, mutect2
- KMT2D | c.2418G>T p.L806= | Silent (SNP) | VAF 144/208 reads (69%) | called by mutect2, varscan2
- MACROH2A2 | c.132C>T p.G44= | Silent (SNP) | VAF 64/143 reads (45%) | catalogued as rs373125930; called by muse, mutect2, varscan2
- MFSD14A | c.1338G>A p.L446= | Silent (SNP) | VAF 102/235 reads (43%) | catalogued as rs1002902904; called by muse, mutect2, varscan2
- MICU1 | c.991C>T p.L331= (on ENST00000361114 / NM_001195518.2; = p.L337= on NM_006077.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 49/134 reads (37%) | called by muse, mutect2, varscan2
- MLF1 | c.36C>T p.D12= | Silent (SNP) | VAF 111/251 reads (44%) | called by muse, mutect2, varscan2
- MSRB3 | c.525C>T p.A175= | Silent (SNP) | VAF 48/175 reads (27%) | catalogued as rs765356027, COSV57591708; called by muse, mutect2, varscan2
- NLRP6 | c.321C>T p.L107= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs1280747031, COSV56459571; called by muse, mutect2, varscan2
- OBSCN | c.16110G>A p.P5370= | Silent (SNP) | VAF 29/37 reads (78%) | catalogued as rs373968488; called by muse, mutect2, varscan2
- PLXNA4 | c.1278G>A p.T426= | Silent (SNP) | VAF 51/120 reads (43%) | catalogued as rs763452302; called by muse, mutect2, varscan2
- RAD54L2 | c.3618G>A p.P1206= | Silent (SNP) | VAF 62/155 reads (40%) | called by muse, mutect2, varscan2
- RP1L1 | c.1605G>A p.S535= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs200772091; ClinVar: benign; called by muse, mutect2, varscan2
- RPUSD4 | c.714G>A p.R238= | Silent (SNP) | VAF 57/205 reads (28%) | called by muse, mutect2, varscan2
- SUMO2 | c.30C>T p.V10= | Silent (SNP) | VAF 55/110 reads (50%) | called by muse, mutect2, varscan2
- TESK1 | c.954G>A p.L318= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV52411862; called by muse, mutect2, varscan2
- TEX15 | c.4620G>A p.E1540= (on ENST00000256246; = p.E1923= on NM_001350162.2) | Silent (SNP) | VAF 69/180 reads (38%) | called by muse, mutect2, varscan2
- WT1 | c.510C>T p.S170= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as rs772890986, COSV60077746; called by muse, mutect2, varscan2
- EPDR1 | c.-217T>A | 5'UTR (SNP) | VAF 92/203 reads (45%) | called by muse, mutect2, varscan2
- HTR4 | c.-34T>C | 5'UTR (SNP) | VAF 55/350 reads (16%) | called by muse, mutect2, varscan2
- IGHD1-1 | chr14:105922617 C>T | 5'Flank (SNP) | VAF 260/349 reads (74%) | called by muse, mutect2, varscan2
- PRMT1 | chr19:49677265 ins T | 5'Flank (INS) | VAF 25/60 reads (42%) | called by mutect2, pindel, varscan2
- SRSF8 | c.*1357_*1359del | 3'UTR (DEL) | VAF 13/51 reads (25%) | called by mutect2, pindel, varscan2
- TSHZ1 | c.*181T>G | 3'UTR (SNP) | VAF 40/136 reads (29%) | catalogued as rs1046379550, COSV100433593; called by muse, mutect2, varscan2
- TSPOAP1 | chr17:58331284 G>A | 5'Flank (SNP) | VAF 53/103 reads (51%) | called by muse, mutect2, varscan2
